Surgical pathology report (de-identified scan), TCGA case TCGA-E3-A3E5, project TCGA-THCA (Thyroid Carcinoma), tissue source site Roswell Park, specimen TCGA-E3-A3E5-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 hx 10/26/11

SPECIMENS:

- A. THYROID GLAND
- B. ? RIGHT PARATHYROID GLAND BIOPSY
- C. RIGHT TRACHEOESOPHAGEAL GROOVE AND SUPERIOR MEDIASTINAL CONTENT
- D. LEVEL 1 LYMPH NODE
- E. RIGHT NECK CONTENTS LEVELS 2,3,4,5
- F. SUPERFICIAL LEVEL 4 TISSUE

SPECIMEN(S):

- A. THYROID GLAND
- B. ? RIGHT PARATHYROID GLAND BIOPSY
- C. RIGHT TRACHEOESOPHAGEAL GROOVE AND SUPERIOR MEDIASTINAL CONTENT
- D. LEVEL 1 LYMPH NODE
- E. RIGHT NECK CONTENTS LEVELS 2,3,4,5
- F. SUPERFICIAL LEVEL 4 TISSUE

DIAGNOSIS:

- A. THYROID, TOTAL THYROIDECTOMY:
- PAPILLARY THYROID CARCINOMA, MULTIFOCAL, INVOLVING BILATERAL LOBES, EXTENDING TO PERITHYROIDAL ADIPOSE TISSUE
- LARGEST TUMOR NODULE MEASURES 1.0 CM
- TWO LYMPH NODES POSITIVE FOR METASTATIC PAPILLARY CARCINOMA (2/2)
- SEE SYNOPTIC REPORT
- B. PARATHYROID GLAND, RIGHT, BIOPSY:
- BENIGN PARATHYROID TISSUE, NEGATIVE FOR CARCINOMA
- C. LYMPH NODE, TRACHEOESOPHAGEAL GROOVE, RIGHT SIDE AND MEDIASTINAL CONTENTS, EXCISION:
- POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (13/15)
- D. LYMPH NODE, RIGHT NECK, LEVEL 1, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- E. NECK, RIGHT, NECK DISSECTION:
- LEVEL 2 LYMPH NODES, POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (6/10)
- LEVEL 3 LYMPH NODES, POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (5/7)
- LEVEL 4 LYMPH NODES, POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (2/9)
- LEVEL 5 LYMPH NODE, NEGATIVE CARCINOMA (0/1)
- F. SOFT TISSUE, NECK, SUPERFICIAL LEVEL 4, EXCISION:
- FIBROADIPOSE TISSUE AND SKELETAL MUSCLE, NEGATIVE FOR CARCINOMA

SYNOPTIC REPORT - THYROID GLAND

Specimens Involved

Specimens: A: THYROID GLAND

C: RIGHT TRACHEOESOPHAGEAL GROOVE AND SUPERIOR MEDIASTINAL CONTENT

D: LEVEL 1 LYMPH NODE

E: RIGHT NECK CONTENTS LEVELS 2,3,4,5

Specimen Type: Total thyroidectomy

Tumor Site: Right lobe

Left lobe

Tumor Focality: Multifocal

Tumor Size (largest nodule): Greatest dimension: 1cm

Additional dimensions: 0.9cm

WHO CLASSIFICATION

Papillary carcinoma 8260/3

[page 2 of 3]
Margins: Margin(s) involved by carcinoma
Site(s) of involvement: RIGHT ANTERIOR
Vascular Invasion: Absent
Additional Pathologic Findings: None identified
Lymph Node: Procedure: Modified radical dissection
Laterality: Right side
Results: Metastatic tumor type: papillary
Located: thyroid
Total positive cervical lymph node: 13 / 28
Level I lymph nodes positive for tumor: 0 / 1
Level II lymph nodes positive for tumor: 6 / 10
Level III lymph nodes positive for tumor: 5 / 7
Level IV lymph nodes positive for tumor: 2 / 9
Level V lymph nodes positive for tumor: 0 / 1
Extracapsular extension by tumor: Absent
Extranodal Extension: Absent
Pathological Staging (pTNM): pT 4a N 1b M X
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. THYROID GLAND

Received fresh labeled with the patient's identification and "thyroid gland" is a 20 g thyroid gland oriented with a single suture designating the left superior pole and a double suture-the right inferior pole. The right lobe is 4.4 x 3 x 0.9 cm, isthmus is 1 x 1 x 0.2 cm and the left lobe is 4.3 x 3.2 x 1.8 cm. The capsule is torn and ragged. Ink code: Right anterior-blue, anterior isthmus-yellow, left anterior lobe-orange, posterior aspect-black. On sectioning, the right lobe contains multiple firm tan nodules ranging from 0.2-0.9 cm. There are colloid nodules, 0.2-0.8 cm. The isthmus and left lobe contain colloid nodules ranging from 0.2-0.4 cm. Tissue is procured. Submitted entirely:

A1: right superior pole, perpendicular sections

A2-A11: right lobe serially submitted from superior to inferior

A12: isthmus

A13-A20: left lobe serially segmented from superior to inferior

B. ? RIGHT PARATHYROID GLAND BIOPSY

Received fresh for frozen section labeled with the patient's identification and '? right parathyroid gland tissue' is a tan pink soft tissue fragment 0.6 x 0.2 x 0.1cm. Toto FSB.

C. RIGHT TRACHEOESOPHAGEAL GROOVE AND SUPERIOR MEDIASTINAL CONTENT

Received fresh labeled with the patient's identification and 'right tracheoesophageal groove and superior mediastinal content' is an unoriented tan pink soft tissue fragment 14 x 3 x 1.8cm. Dissection reveals sixteen lymph nodes ranging from 0.2 x 0.2 x 0.2cm to 2.5 x 2.4 x 2cm. The largest lymph nodes are sectioned to reveal a tan red-homogenous cut surface. A portion of the specimen is submitted for tissue procurement.

C1: four lymph nodes

C2: four lymph nodes

C3: five lymph nodes

C4: one lymph node

C5: one lymph node

C6: largest lymph node

D. LEVEL 1 LYMPH NODE

Received fresh labeled with the patient's identification and 'level 1 lymph node' is a tan pink lymph node 1.3 x 1.3 x 0.7cm. The specimen is trisected. Toto D1.

E. RIGHT NECK CONTENTS LEVELS 2,3,4,5

Received fresh labeled with the patient's identification and 'right neck contents levels 2,3,4 and 5' is an oriented tan pink soft tissue fragment 16 x 14 x 3cm. The specimen is divided in to levels 2,3,4 and 5. Level II is 10 x 7 x 3cm. Dissection reveals eleven lymph nodes ranging from 0.3 x 0.2 x 0.2cm to 6.5 x 3.4 x 3cm. Level III is 5.5 x 3.5 x 2cm. Dissection reveals seven lymph nodes ranging from 0.5 x 0.4 x 0.4cm to 1.7 x 0.8 x 0.8cm. Level IV is 7.5 x 4.3 x 3cm. Dissection reveals nine lymph nodes ranging from 0.3 x 0.2 x 0.2cm to 3 x 2 x 2cm. Level V is 5 x 2.8 x 2.2cm. Dissection reveals one lymph node 1.3 x 1 x 0.5cm. A portion of the specimen is submitted for tissue procurement.

Level II

E1: four lymph nodes

E2: three lymph nodes

[page 3 of 3]
E3: two lymph nodes
E4-E5: one lymph node
E6-E7: representative section of largest lymph node
Level III
E8: four lymph nodes
E9: three lymph nodes
Level IV
E10: four lymph nodes
E11: four lymph nodes
E12: representative sections of largest lymph node
Level V
E13: one lymph node
F. SUPERFICIAL LEVEL 4 TISSUE

Received in formalin labeled with the patient's identification and designated "superficial level 4 tissue" is an unoriented fragment of red-tan soft tissue measuring 4 x 2.5 x 0.4 CM. Entirely submitted, F1-F3.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Thyroid cancer

INTRAOPERATIVE CONSULTATION:

FSB- ? Right parathyroid gland biopsy: Parathyroid tissue. Diagnosis called to Dr. at _____ by Dr.

Microscopic/Diagnostic Dictation: ,
Final Review: , M.D., Pathologist,
Final Review: , M.D., Pathologist*
Final: , M.D., Pathologist,

Source: NCI Genomic Data Commons file 0cf25237-e358-42ec-bb1b-cebbee693c2f (TCGA-E3-A3E5.8BE54EAA-1E14-4257-A78E-B1A4782FC9D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).